Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MP, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MP-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

JATABASE

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

- Left inguinal dissection (loop mark superior) - metastatic melanoma left thigh lymph node (half to tumour bank) long stitch mark the other half.

MACROSCOPIC DESCRIPTION

(Dr

"LEFT INGUINAL LYMPH NODE SUPERIOR". Fatty tissue, specimen received in formalin. Fatty tissue 200 x 100 x 40mm with overlying ellipse of skin 180 x 15mm. The skin appear unremarkable. A loop stitch is present marking superior. A variegated lymph node is present (with a long black stitch) up to 13mm across.

- A. One node bisected (closest to the loop stitch).
- B. Four nodes.
- C. One node bisected.
- D. Four nodes.
- E. One node bisected.
- F. One node bisected.
- G. One node bisected.
- H. One node bisected.
- J. Variegated nodule bisected.
- K. One node bisected.
- L. One node bisected.
- M. Two lymph nodes.

1CD-0-3
Melanoma, NOS 8720/3
Site: lymph node, inguinal
C77.4

WJ
8/24/11

MICROSCOPIC REPORT

"LEFT INGUINAL LYMPH NODE SUPERIOR".

A total of 19 lymph nodes were retrieved, including one tumour nodule assumed to represent complete replacement of a lymph node by metastatic melanoma. This is characterised by pleomorphic epithelioid cells with large, oval nuclei, prominent nucleoli and inconspicuous amphophilic cytoplasm. Numerous mitoses are seen and there are areas of necrosis. The tumour cells show strong nuclear and cytoplasmic immunohistochemical staining for S100, and are also Melan A and HMB45 positive (with focal strong staining for HMB45) (1/19).

SUMMARY

Left inguinal lymph nodes - METASTATIC MELANOMA IN 1 OF 19 LYMPH NODES (1/19).

REPORTED BY: Dr.

Source: NCI Genomic Data Commons file a82ce6f9-ce82-4b59-a692-f00680156bbd (TCGA-EE-A2MP.F725CFD4-E7FE-47E3-A77E-13AF89304C29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).